Somatic mutation profile of tumor specimen TCGA-20-1687-01A (aliquot TCGA-20-1687-01A-01W-0633-09) from TCGA case TCGA-20-1687, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IV; Tumor grade: G3; Age at diagnosis: 46.4 years (16,961 days).
Specimen TCGA-20-1687-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8c4ef619-c834-4945-b4c0-09ac1476fc9e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-20-1687-10A (Blood Derived Normal), aliquot TCGA-20-1687-10A-01W-0633-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1a85963f-f394-4851-9047-c5eb0fa28519

The open-access MAF lists 83 somatic variants for this specimen: 63 protein-altering or splice-affecting, 18 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 51, Silent 18, Nonsense Mutation 5, Splice Site 3, Frame Shift Del 3, 5'UTR 1, Intron 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTEN | c.634+1G>T p.X212_splice | Splice Site (SNP) | VAF 8/192 reads (4%) | hotspot (GDC flag); catalogued as CS110219, CS1314438, COSV64295775, COSV64297457, COSV64302278; called by muse, mutect2
- TP53 | c.469G>T p.V157F | Missense Mutation (SNP) | VAF 39/51 reads (76%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs121912654, CM137621, COSV52667015, COSV52676009, COSV52752314, COSV53205488; ClinVar: uncertain significance / likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ANO5 | c.1155C>A p.F385L | Missense Mutation (SNP) | VAF 67/79 reads (85%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.544); catalogued as COSV61086936; called by muse, mutect2, varscan2
- ANTXR1 | c.1683G>T p.R561S | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.021); catalogued as COSV100362128; called by muse, mutect2
- ARHGAP36 | c.1529C>A p.S510Y | Missense Mutation (SNP) | VAF 34/110 reads (31%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.641); catalogued as COSV52268480; called by muse, mutect2, varscan2
- ARHGEF40 | c.1075G>T p.G359* | Nonsense Mutation (SNP) | VAF 4/28 reads (14%) | catalogued as COSV53881503; called by muse, mutect2, varscan2
- ASAH2 | c.83T>A p.L28H | Missense Mutation (SNP) | VAF 43/105 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.95); catalogued as COSV100269852; called by muse, mutect2, varscan2
- CATSPERB | c.81T>A p.D27E | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.017); catalogued as COSV56428879; called by muse, mutect2, varscan2
- CCT8L2 | c.773C>T p.T258M | Missense Mutation (SNP) | VAF 16/96 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as rs147789853, CM142324; called by muse, mutect2, varscan2
- CDRT1 | c.704C>T p.S235F | Missense Mutation (SNP) | VAF 13/98 reads (13%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.641); catalogued as COSV55412226; called by muse, mutect2, varscan2
- CERS4 | c.71A>T p.E24V | Missense Mutation (SNP) | VAF 21/116 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV52168065; called by muse, mutect2, varscan2
- CFAP126 | c.210G>A p.M70I | Missense Mutation (SNP) | VAF 83/188 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.31); catalogued as COSV61368683; called by muse, mutect2, varscan2
- CHD2 | c.2030A>C p.D677A | Missense Mutation (SNP) | VAF 73/83 reads (88%) | SIFT tolerated (0.14); PolyPhen benign (0.044); catalogued as COSV67711008; called by muse, mutect2, varscan2
- CHRNA3 | c.1023G>T p.W341C | Missense Mutation (SNP) | VAF 23/181 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58776054; called by muse, mutect2, varscan2
- COL4A1 | c.3248A>T p.E1083V | Missense Mutation (SNP) | VAF 37/219 reads (17%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.958); catalogued as COSV65427705; called by muse, mutect2, varscan2
- CPAMD8 | c.4471C>A p.L1491M (on ENST00000651564; = p.L1444M on NM_015692.5) | Missense Mutation (SNP) | VAF 16/73 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.715); catalogued as COSV101488440; called by muse, mutect2
- CRISPLD2 | c.1277C>T p.P426L | Missense Mutation (SNP) | VAF 37/108 reads (34%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.774); catalogued as rs369151118; called by muse, mutect2, varscan2
- CYB561 | c.139_151del p.D47Tfs*9 | Frame Shift Del (DEL) | VAF 8/10 reads (80%) | catalogued as COSV62539946; called by mutect2, varscan2
- DCAF12L2 | c.1169G>A p.S390N | Missense Mutation (SNP) | VAF 53/83 reads (64%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV63582531; called by muse, mutect2, varscan2
- DGKK | c.3358T>G p.F1120V | Missense Mutation (SNP) | VAF 25/78 reads (32%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.968); catalogued as COSV101052931; called by muse, mutect2, varscan2
- DIS3L | c.1139G>C p.S380T (on ENST00000319212 / NM_001143688.3; = p.S297T on NM_133375.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 38/221 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.07); catalogued as COSV59913056; called by muse, mutect2, varscan2
- DNAH8 | c.4085G>T p.W1362L | Missense Mutation (SNP) | VAF 67/270 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV59458335; called by muse, mutect2, varscan2
- GTF2IRD2B | c.2627C>T p.T876M | Missense Mutation (SNP) | VAF 21/212 reads (10%) | SIFT tolerated (0.05); PolyPhen benign (0.005); catalogued as rs1554532497, COSV57031448; called by muse, mutect2, varscan2
- HEPHL1 | c.1468T>A p.Y490N | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100243688; called by muse, mutect2, varscan2
- HEPHL1 | c.1469A>T p.Y490F | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT tolerated (0.23); PolyPhen benign (0.253); catalogued as COSV100243691; called by muse, mutect2, varscan2
- IGKV2D-29 | c.131A>G p.K44R | Missense Mutation (SNP) | VAF 44/100 reads (44%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV72391580; called by muse, mutect2, varscan2
- IGSF9 | c.773C>T p.T258I | Missense Mutation (SNP) | VAF 18/100 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63640714; called by muse, mutect2, varscan2
- IL12RB1 | c.796G>T p.E266* | Nonsense Mutation (SNP) | VAF 11/26 reads (42%) | catalogued as COSV59097808; called by muse, mutect2, varscan2
- ITSN2 | c.397C>G p.P133A | Missense Mutation (SNP) | VAF 62/132 reads (47%) | SIFT tolerated (0.35); PolyPhen benign (0.035); catalogued as rs144746035, COSV61949590; called by muse, mutect2, varscan2
- KAT6B | c.2623G>A p.D875N | Missense Mutation (SNP) | VAF 51/272 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as COSV54742713; called by muse, mutect2, varscan2
- KCNMB1 | c.442T>A p.F148I | Missense Mutation (SNP) | VAF 44/115 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.024); catalogued as COSV51133125; called by muse, mutect2, varscan2
- LPXN | c.882T>A p.F294L | Missense Mutation (SNP) | VAF 51/79 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV67717496; called by muse, mutect2, varscan2
- MEP1A | c.263-1G>T p.X88_splice | Splice Site (SNP) | VAF 46/211 reads (22%) | catalogued as COSV100042481; called by muse, varscan2
- MEP1A | c.338A>G p.Y113C | Missense Mutation (SNP) | VAF 48/220 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs774129862, COSV57921004; called by muse, varscan2
- MFSD2A | c.725C>A p.T242K (on ENST00000372809 / NM_001136493.3; = p.T229K on NM_032793.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 21/63 reads (33%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.606); catalogued as COSV65685960; called by muse, mutect2, varscan2
- MME | c.761G>C p.R254T | Missense Mutation (SNP) | VAF 196/340 reads (58%) | SIFT tolerated (0.62); PolyPhen benign (0.003); catalogued as COSV64708434; called by muse, mutect2, varscan2
- NBAS | c.211C>G p.P71A | Missense Mutation (SNP) | VAF 29/71 reads (41%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.656); catalogued as COSV55727018; called by muse, mutect2, varscan2
- NUP210L | c.1072T>A p.F358I | Missense Mutation (SNP) | VAF 46/112 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.086); catalogued as COSV55142356, COSV55150733; called by muse, mutect2, varscan2
- PBLD | c.513-2A>C p.X171_splice | Splice Site (SNP) | VAF 50/150 reads (33%) | catalogued as COSV53266475; called by muse, mutect2, varscan2
- PCDHAC2 | c.1987C>T p.R663* | Nonsense Mutation (SNP) | VAF 8/81 reads (10%) | catalogued as rs782591270, COSV53850572; called by muse, mutect2
- PLB1 | c.3379T>C p.W1127R | Missense Mutation (SNP) | VAF 8/86 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59829007, COSV59831477; called by muse, mutect2
- PODN | c.1283G>A p.R428H (on ENST00000395871; = p.R380H on NM_153703.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 7/11 reads (64%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.975); catalogued as rs1417440191, COSV57013551, COSV57014799; called by muse, mutect2, varscan2
- PRKACA | c.643G>C p.G215R | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58068670; called by muse, mutect2, varscan2
- RAD21 | c.100G>C p.E34Q | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV52060606, COSV52062878; called by muse, mutect2, varscan2
- RFFL | c.94C>A p.P32T | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.471); catalogued as COSV52072610; called by muse, mutect2, varscan2
- SEMA5A | c.307G>A p.A103T | Missense Mutation (SNP) | VAF 35/185 reads (19%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.714); catalogued as rs778349906, COSV66797389; called by muse, mutect2, varscan2
- SLC30A8 | c.954T>G p.H318Q | Missense Mutation (SNP) | VAF 152/247 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV69972560; called by muse, mutect2, varscan2
- SPHKAP | c.116A>T p.N39I | Missense Mutation (SNP) | VAF 10/160 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.07); catalogued as COSV60867879; called by muse, mutect2
- SZT2 | c.9592C>T p.Q3198* (on ENST00000634258 / NM_001365999.1; = p.Q3141* on NM_015284.4) | Nonsense Mutation (SNP) | VAF 5/22 reads (23%) | catalogued as COSV65094841; called by muse, mutect2, varscan2
- TATDN2 | c.2068G>T p.A690S | Missense Mutation (SNP) | VAF 34/204 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.877); catalogued as COSV55052557; called by muse, mutect2, varscan2
- TDGF1 | c.291C>A p.C97* | Nonsense Mutation (SNP) | VAF 58/136 reads (43%) | catalogued as COSV56126820; called by muse, mutect2, varscan2
- TECTA | c.2835G>T p.Q945H | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT tolerated (0.55); PolyPhen probably damaging (0.947); catalogued as COSV50732287, COSV99878324; called by muse, mutect2, varscan2
- THADA | c.127G>A p.V43M | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.391); catalogued as COSV67090922; called by muse, mutect2, varscan2
- WNT2B | c.877C>T p.R293C (on ENST00000369684 / NM_024494.3; = p.R274C on NM_004185.4) | Missense Mutation (SNP) | VAF 39/60 reads (65%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.766); catalogued as rs760453981, COSV56675195; called by muse, mutect2, varscan2
- ZFHX4 | c.837G>T p.M279I | Missense Mutation (SNP) | VAF 33/187 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV51452765; called by muse, mutect2, varscan2
- ZNF256 | c.176G>T p.G59V | Missense Mutation (SNP) | VAF 17/100 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.019); catalogued as COSV56598117; called by muse, mutect2, varscan2
- ZZEF1 | c.1682C>T p.T561M | Missense Mutation (SNP) | VAF 39/96 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1457631843, COSV67557659; called by muse, mutect2, varscan2
- CHRNA2 | c.1087C>T p.P363S | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (0.15); PolyPhen benign (0.206); called by muse, mutect2, varscan2
- FCGBP | c.8123C>G p.A2708G | Missense Mutation (SNP) | VAF 11/134 reads (8%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.977); called by muse, mutect2
- GRIN3A | c.1391del p.F464Sfs*52 | Frame Shift Del (DEL) | VAF 82/258 reads (32%) | called by pindel, varscan2
- IGLV3-22 | c.251C>T p.T84I | Missense Mutation (SNP) | VAF 54/92 reads (59%) | SIFT tolerated (0.06); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- MOSPD2 | c.1351_1354del p.N451Lfs*4 | Frame Shift Del (DEL) | VAF 44/103 reads (43%) | called by mutect2, pindel, varscan2
- UBB | c.114dup p.D39Rfs*20 | Frame Shift Ins (INS) | VAF 4/40 reads (10%) | called by pindel, varscan2
- ARNT2 | c.651G>A p.T217= | Silent (SNP) | VAF 19/177 reads (11%) | catalogued as rs771097823, COSV57585565; called by muse, mutect2, varscan2
- ASAH2 | c.84C>A p.L28= | Silent (SNP) | VAF 43/104 reads (41%) | catalogued as COSV100269850, COSV61483172, COSV61483522; called by muse, mutect2, varscan2
- C16orf71 | c.180C>A p.S60= | Silent (SNP) | VAF 17/33 reads (52%) | catalogued as COSV58509584; called by muse, mutect2, varscan2
- CECR2 | c.2481C>T p.H827= (on ENST00000342247 / NM_001290047.2; = p.H644= on NM_001290046.1) | Silent (SNP) | VAF 45/109 reads (41%) | catalogued as rs760517770, COSV52843917; called by muse, mutect2, varscan2
- DNAH7 | c.2988T>A p.S996= | Silent (SNP) | VAF 60/193 reads (31%) | catalogued as COSV56771493; called by muse, mutect2, varscan2
- FRAS1 | c.7998T>A p.I2666= | Silent (SNP) | VAF 28/37 reads (76%) | catalogued as COSV53622406; called by muse, mutect2, varscan2
- GNB1 | c.342C>T p.C114= | Silent (SNP) | VAF 13/62 reads (21%) | catalogued as rs556077872, COSV66100531; called by muse, mutect2, varscan2
- HIVEP3 | c.2607A>G p.T869= | Silent (SNP) | VAF 8/100 reads (8%) | catalogued as COSV99911915; called by muse, mutect2
- IGKV3-7 | c.66T>A p.I22= | Silent (SNP) | VAF 53/383 reads (14%) | catalogued as rs765814474; called by muse, mutect2, varscan2
- KRT36 | c.168C>A p.L56= | Silent (SNP) | VAF 13/46 reads (28%) | catalogued as COSV60203795; called by muse, mutect2, varscan2
- MC3R | c.114C>T p.V38= | Silent (SNP) | VAF 252/455 reads (55%) | catalogued as COSV54763156, COSV54764184; called by muse, mutect2, varscan2
- NHLRC2 | c.1122C>G p.G374= | Silent (SNP) | VAF 58/311 reads (19%) | catalogued as COSV65175226; called by muse, mutect2, varscan2
- NUTM2F | c.1857T>A p.P619= | Silent (SNP) | VAF 4/12 reads (33%) | catalogued as COSV53558373; called by mutect2, varscan2
- SUPT7L | c.474C>G p.L158= | Silent (SNP) | VAF 15/84 reads (18%) | catalogued as COSV61823108; called by muse, mutect2, varscan2
- SYNE2 | c.561T>A p.L187= | Silent (SNP) | VAF 197/341 reads (58%) | catalogued as COSV58361381; called by muse, mutect2, varscan2
- TTN | c.43761C>T p.R14587= (on ENST00000591111; = p.R7163= on NM_003319.4) | Silent (SNP) | VAF 9/17 reads (53%) | catalogued as rs529418633, COSV59868742; called by muse, mutect2, varscan2
- UNC13C | c.3060G>A p.Q1020= | Silent (SNP) | VAF 7/42 reads (17%) | catalogued as COSV52890317; called by muse, mutect2, varscan2
- USP6 | c.3489C>A p.L1163= | Silent (SNP) | VAF 54/64 reads (84%) | catalogued as COSV51486317; called by muse, mutect2, varscan2
- DST | c.4297-1886A>C | Intron (SNP) | VAF 27/246 reads (11%) | catalogued as COSV55023120; called by muse, mutect2, varscan2
- SLC2A5 | c.-1C>T | 5'UTR (SNP) | VAF 25/118 reads (21%) | catalogued as COSV101072629; called by muse, mutect2, varscan2
